Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4983, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4983-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA-BP-4983

Clinical Diagnosis & History:

with right renal mass.

Specimens Submitted:

1: SP: KIDNEY, RIGHT; RADICAL NEPHRECTOMY

2: SP: SOFT TISSUE, PERINEPHRIC FAT; EXCISION

DIAGNOSIS:

1. SP: KIDNEY, RIGHT; RADICAL NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 6.3 cm.

Local Invasion (for renal cortical types):

Extends into renal pelvis

Renal Vein Invasion:

Not identified

Tumor involves medium caliber vessels in the renal sinus

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Chronic interstitial inflammation and focal hyalinized glomeruli

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3 Tumor extends into major veins or invades the adrenal gland or perinephric tissues, but not beyond Gerota's fascia

2. SP: SOFT TISSUE, PERINEPHRIC FAT; EXCISION:

Benign fibroadipose tissue.

[page 2 of 3]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

1). The specimen is received fresh labeled "right radical nephrectomy" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 190 g in total. The kidney measures 10.5 x 6.5 x 5.5 cm. The attached ureter measures 2.4 cm in length and 0.3 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. The kidney is inked blue and bivalved to reveal a cortical tumor located in the upper pole of the kidney and measuring 6 x 6.3 x 4 cm. The tumor is separated from the normal parenchyma by a thin capsule and grossly does not invade the cortex and the perinephric fat. Focally it is situated inside the calyces. The tumor has a rubbery variegated white tan cut surface. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.6 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

TC--tumor with calyces

RP -- renal pelvis representative sections

K -- representative sections kidney

2). The specimen is received in formalin, labeled "Perinephric fat". It consist of multiple fragments of pale tan unremarkable fatty tissue measuring 9 x 7 x 0.5 cm in aggregate. No lymph nodes are identified. Representatively submitted.

Summary of sections:

U-undesigned

Summary of Sections:

Part 1: SP: KIDNEY, RIGHT; RADICAL NEPHRECTOMY

Block	Sect. Site	PCs
1	{not entered}	1
1	K	1
1	RP	1
4	T	4
3	TC	3
1	THF	1
1	TK	1
1	TSF	1
1	UVM	1

Part 2: SP: SOFT TISSUE, PERINEPHRIC FAT; EXCISION

Block	Sect. Site	PCs
2	U	4

[page 3 of 3]
Intraoperative Consultation:

The opinion given in this section pertains to a gross examination at the time of intraoperative consultation.

- 1) INTRAOPERATIVE CONSULTATION (GROSS): RENAL CORTICAL NEOPLASM [REDACTED]
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 1e68233c-7da9-44f3-b82a-bcf28053c69c (TCGA-BP-4983.4CCC9E93-1186-42B3-8F16-5A58FEFF01A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).